Gene-level copy-number profile of tumor specimen TCGA-39-5016-01A from TCGA case TCGA-39-5016, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 44.6 years (16,306 days).
Specimen TCGA-39-5016-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.04ae973c-33a1-4967-9103-0a604b04fa67.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-39-5016-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a472908d-2f1b-4d1d-bd71-9af8a770c6f1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 211; copy number 2: 27,153; copy number 3: 12,909; copy number 4: 13,107; copy number 5: 4,608; copy number 6: 77; copy number 7: 1,111; copy number 8: 116; copy number 9: 188; copy number 10: 114; copy number 11: 146; copy number 12: 68.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-39-5016-01A-01D-1439-01): tumor purity 0.51, ploidy 3.01, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,427 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:228,735,479–246,528,841, 337 genes, copy number 5 (broad region; genes not listed).
- chr2:97,913,054–133,568,463, 692 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr2:172,137,345–242,160,153, 1,278 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:95,654,423–98,901,695, 58 genes, copy number 5 (within-gene range 3–5): MTHFD2P1, AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1, EPHA6, AC117470.1, AC110491.1, ARL6, AC110491.3, CRYBG3, AC110491.2, RIOX2, AC026100.1, GABRR3, OR5BM1P, OR5AC1, OR5AC2, AC117460.1, OR5AC4P, POU5F1P7, OR5H1, OR5H14, OR5H15, OR5H5P, OR5H3P, OR5H4P, AC117473.1, OR5H7P, OR5H6, OR5H2, OR5H8, OR5K4, OR5K3, UBFD1P1, OR5K1, OR5K2, CLDND1, AC021660.3, AC021660.2, RPL38P4, GPR15, AC021660.4, CPOX, AC021660.1, WWP1P1, ST3GAL6-AS1, ST3GAL6, PDLIM1P4, DCBLD2, RNU6-26P.
- chr3:134,477,706–198,222,513, 1,097 genes, copy number 5–12 (broad region; genes not listed).
- chr4:49,588,772–57,658,800, 123 genes, copy number 5–10 (within-gene range 3–10) (broad region; genes not listed).
- chr4:174,636,920–174,829,247, 1 gene, copy number 9: GLRA3.
- chr5:58,198–14,532,128, 256 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:63,011,463–75,528,148, 341 genes, copy number 7 (broad region; genes not listed).
- chr7:76,326,799–107,564,261, 569 genes, copy number 7–11 (within-gene range 3–11) (broad region; genes not listed).
- chr8:8,783,354–11,201,833, 59 genes, copy number 6 (within-gene range 2–6): MFHAS1, RNU6-682P, AC087763.1, RPL10P19, SNORA70, ERI1, MIR4660, RNU7-55P, Metazoa_SRP, PPP1R3B, AC022784.5, AC022784.1, AC022784.6, AC022784.2, AC022784.4, AC022784.3, RNU6-1151P, AC021736.1, AC021242.2, RNU6-526P, AC021242.1, AC021242.3, TNKS, AC103834.1, MIR597, MIR124-1HG, MIR124-1, AC034111.2, AC034111.1, MSRA, AC023385.1, AC079200.1, AC112673.1, AC104964.2, LINCR-0001, PRSS52P, RNU6-729P, AC104964.1, PRSS51, AC104964.3, PRSS55, RP1L1, MIR4286, C8orf74, RNA5SP252, SOX7, AC105001.2, AC105001.1, PINX1, MIR1322, AC011008.1, AC011008.2, XKR6, MIR598, AF131215.3, AF131215.6, AF131215.5, AF131215.4, AF131215.2.
- chr10:132,808,392–133,761,125, 58 genes, copy number 5 (within-gene range 3–5): CFAP46, LINC01166, LINC01167, LINC01168, ADGRA1, ADGRA1-AS1, RPL5P28, KNDC1, UTF1, VENTX, MIR202HG, MIR202, AL592071.1, ADAM8, TUBGCP2, AL360181.2, ZNF511, ZNF511-PRAP1, CALY, BANF1P2, AL360181.1, PRAP1, FUOM, ECHS1, MIR3944, AL360181.4, PAOX, AL360181.3, MTG1, SPRN, OR6L2P, SCART1, OR7M1P, CYP2E1, AL161645.1, AL161645.2, SYCE1, AL731769.2, OR6L1P, AL731769.1, FRG2B, RARRES2P2, AGGF1P2, CLUHP5, DUX4L28, DUX4L25, DUX4L24, DUX4L23, DUX4L22, DUX4L21, DUX4L20, DUX4L29, DUX4L10, DUX4L11, DUX4L12, DUX4L13, DUX4L14, DUX4L15.
- chr12:90,107,739–92,142,914, 24 genes, copy number 7–11 (within-gene range 3–11): AC126178.1, LINC02392, LINC02822, AC084365.1, AC112481.2, AC112481.1, CCER1, LINC00615, EPYC, KERA, LUM, DCN, AC007115.1, LINC02823, AC090016.1, AC126175.1, AC126175.2, AC025254.1, AC090049.2, LINC02404, AC090049.1, LINC01619, AC123512.1, AC025164.2.
- chr17:55,448,433–83,095,122, 890 genes, copy number 5 (broad region; genes not listed).
- chr18:67,672,221–67,767,051, 1 gene, copy number 9 (within-gene range 4–9): AC022655.1.
- chr18:67,788,268–69,055,189, 20 genes, copy number 9: AC114689.1, LINC01903, AC114689.2, AC100844.1, AC068112.1, AC005909.2, LINC01912, AC022968.1, AC005909.1, AKR1B10P2, MTL3P, TMX3, CCDC102B, AC040896.1, AC022035.1, RNU6-39P, SDHCP1, AC096708.2, AC096708.3, AC096708.1.
- chr18:71,000,477–72,638,521, 13 genes, copy number 6–7 (within-gene range 2–7): AC090415.2, AC090415.1, AC091691.3, AC091691.2, AC091691.1, LINC01541, AC090312.1, AC090312.2, LINC01899, AC027458.1, AC069114.1, AC069114.2, CBLN2.
- chr20:30,484,925–43,895,468, 350 genes, copy number 5–7 (broad region; genes not listed).
- chr22:25,742,144–34,218,796, 260 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 208. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
